Somatic mutation profile of tumor specimen TCGA-B9-4617-01A (aliquot TCGA-B9-4617-01A-01D-1252-08) from TCGA case TCGA-B9-4617, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 41.2 years (15,053 days).
Specimen TCGA-B9-4617-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9d2609f-1da1-4ac5-8623-8fd35c0bb129.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-4617-10A (Blood Derived Normal), aliquot TCGA-B9-4617-10A-01D-1252-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d7a8c01-3011-4976-93f7-a1ca57bb1aa6

The open-access MAF lists 57 somatic variants for this specimen: 47 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 9, Frame Shift Del 4, Nonsense Mutation 2, 5'UTR 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.751T>C p.C251R | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV60913490, COSV60913700; called by muse, mutect2, varscan2
- ACIN1 | c.60T>G p.N20K | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); catalogued as COSV52975754; called by muse, mutect2, varscan2
- AKAP6 | c.4222G>A p.V1408M | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); catalogued as COSV55212244; called by muse, mutect2, varscan2
- ARHGEF40 | c.2189C>G p.A730G | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV53879950; called by muse, mutect2, varscan2
- C11orf65 | c.543A>G p.I181M | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV67597385; called by muse, mutect2, varscan2
- C17orf100 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs1441835415; called by muse, mutect2
- CDK13 | c.3112T>C p.S1038P | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as COSV51699208; called by muse, mutect2, varscan2
- CSNK2A1 | c.1039A>G p.S347G | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV53934926; called by muse, mutect2, varscan2
- CUX1 | c.1114G>A p.A372T (on ENST00000292535 / NM_181552.4; = p.A383T on NM_001913.5) | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs782084566, COSV52897791; called by muse, mutect2, varscan2
- CYP20A1 | c.973T>C p.Y325H | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61909416; called by muse, mutect2, varscan2
- DARS1 | c.804T>G p.I268M | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51537900; called by muse, mutect2, varscan2
- DDX55 | c.523A>T p.R175* | Nonsense Mutation (SNP) | VAF 80/133 reads (60%) | catalogued as COSV53015987; called by muse, varscan2
- GLS | c.1958A>G p.D653G | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV57841370; called by muse, mutect2, varscan2
- GNA13 | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 192/358 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as COSV71474685; called by muse, mutect2
- HDLBP | c.3305C>G p.T1102S | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as COSV60494904; called by muse, mutect2, varscan2
- JUNB | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56877815; called by muse, mutect2
- LRP4 | c.3670C>T p.Q1224* | Nonsense Mutation (SNP) | VAF 40/98 reads (41%) | catalogued as COSV66135506; called by muse, mutect2, varscan2
- LRP6 | c.1933A>C p.I645L | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.513); catalogued as COSV53786767; called by muse, mutect2, varscan2
- MAGEB4 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as COSV66775674; called by muse, mutect2, varscan2
- MAP3K14 | c.1330T>C p.C444R | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV60923467; called by muse, mutect2, varscan2
- MAP3K20 | c.1130G>T p.R377L | Missense Mutation (SNP) | VAF 154/288 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV64378054; called by muse, mutect2, varscan2
- MRM3 | c.866A>T p.N289I | Missense Mutation (SNP) | VAF 192/350 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58679675; called by muse, mutect2, varscan2
- MRM3 | c.1087A>C p.S363R | Missense Mutation (SNP) | VAF 89/151 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58679683; called by muse, mutect2, varscan2
- NIT1 | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.262); catalogued as COSV63501552; called by muse, mutect2, varscan2
- OR2B3 | c.37A>C p.I13L | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV65850895; called by muse, mutect2, varscan2
- OR5I1 | c.41T>A p.F14Y | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV56886712; called by muse, mutect2, varscan2
- PCDH1 | c.3676G>C p.A1226P | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs1320364118, COSV54613544, COSV54613683; called by muse, mutect2, varscan2
- PCF11 | c.1786A>G p.R596G | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53530551, COSV53532229; called by muse, mutect2, varscan2
- PPIG | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as COSV53642739; called by muse, mutect2, varscan2
- PRH1 | c.116A>T p.E39V | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV70372028; called by muse, mutect2, varscan2
- REC8 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 139/390 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs747615352, COSV61016483; called by muse, mutect2, varscan2
- RUVBL1 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 89/252 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100494234, COSV59475801; called by muse, mutect2, varscan2
- SCN4A | c.4045C>T p.L1349F | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs994344058, COSV71126654; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC13A1 | c.905G>C p.W302S | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52010694; called by muse, mutect2, varscan2
- SNIP1 | c.77G>C p.G26A | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs747496092; called by muse, mutect2
- SNRNP48 | c.482G>C p.R161P | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60939331; called by muse, mutect2, varscan2
- ZC3H7A | c.1656G>T p.K552N | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV63269394; called by muse, mutect2, varscan2
- ITLN2 | c.66T>A p.S22R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, varscan2
- LRRC37A | c.4373C>A p.P1458H | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MCCC2 | c.999+3_999+4dup p.X333_splice | Splice Site (INS) | VAF 43/115 reads (37%) | called by mutect2, pindel, varscan2
- MESP1 | c.706C>G p.P236A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); called by muse, mutect2
- NOX3 | c.313del p.V105Sfs*5 | Frame Shift Del (DEL) | VAF 160/495 reads (32%) | called by mutect2, pindel, varscan2
- OR11H1 | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by mutect2, varscan2
- PKN1 | c.348dup p.G117Wfs*22 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- SLIT3 | c.2780del p.N927Ifs*46 | Frame Shift Del (DEL) | VAF 36/86 reads (42%) | called by mutect2, pindel, varscan2
- WDFY3 | c.8126del p.L2709* | Frame Shift Del (DEL) | VAF 86/224 reads (38%) | called by mutect2, pindel, varscan2
- XPNPEP2 | c.767_768del p.I256Tfs*3 | Frame Shift Del (DEL) | VAF 168/245 reads (69%) | called by mutect2, pindel, varscan2
- ECE1 | c.648C>A p.A216= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV51664031, COSV51669612; called by muse, mutect2, varscan2
- HLF | c.783G>A p.E261= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV56829804, COSV56832368; called by muse, mutect2, varscan2
- KAT6B | c.282G>T p.G94= | Silent (SNP) | VAF 139/441 reads (32%) | catalogued as COSV54745991; called by muse, mutect2, varscan2
- KCNC4 | c.1815G>A p.R605= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV63925550; called by muse, mutect2, varscan2
- MAP3K6 | c.3699C>T p.G1233= | Silent (SNP) | VAF 49/99 reads (49%) | catalogued as COSV58871527; called by muse, mutect2, varscan2
- NEURL4 | c.873C>T p.N291= | Silent (SNP) | VAF 105/187 reads (56%) | catalogued as COSV59758480; called by muse, mutect2, varscan2
- PMEL | c.1429C>T p.L477= | Silent (SNP) | VAF 89/166 reads (54%) | catalogued as COSV59385810; called by muse, mutect2, varscan2
- RBM4 | c.942T>A p.A314= | Silent (SNP) | VAF 54/147 reads (37%) | catalogued as COSV59518679; called by muse, mutect2, varscan2
- ZNF501 | c.168A>G p.G56= | Silent (SNP) | VAF 57/190 reads (30%) | catalogued as COSV101247160, COSV68516279, COSV68516668; called by muse, mutect2, varscan2
- RAD51AP2 | c.-3_-2del | 5'UTR (DEL) | VAF 60/187 reads (32%) | called by mutect2, pindel, varscan2
